Surgical pathology report (de-identified scan), TCGA case TCGA-DV-A4W0, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-A4W0-05A (Additional - New Primary).

[page 1 of 4]
MEDICAL RECORD

Surgical Pathology Report

Surgical Pathology Report

ICB-0-3
Carcinoma, renal cell, NOS
Site: Kidney, NOS C4.9
8312/3
hw
12/15/14

PATIENT:
ACCOUNT#:
DOB:
AGE:
ATTENDING:
REQUESTING:
CONTACT NO:
COPIES TO:

SEX: M

MRN:
RECEIVED DATE:
PROCEDURE DATE:
SIGN-OUT DATE:
LOCATION:
ROOM:

DIAGNOSIS:

1. Renal mass, right, tumor #1 (resection): Renal cyst lined by atypical clear cells.
2. Renal mass, right tumor #2 (resection): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II.
3. Renal mass, tumor #3 (resection): Renal cell carcinoma with clear and papillary cell features, see note.
4. Renal mass, right, tumor #4 (resection): Renal cysts lined by atypical clear cells.
5. Renal mass, right, tumor #5 (resection): Renal cell carcinoma with clear and tubular features, Fuhrman nuclear grade II.
6. Renal mass, right, tumor #6 (resection): Renal cell carcinoma with clear and tubular features, Fuhrman nuclear grade II.
7. Renal mass, right, tumor #7 (resection): Renal cyst lined by atypical clear cells.
8. Renal mass, right, tumor #8 (resection): Renal cell carcinoma with clear and tubular features, Fuhrman nuclear grade II.
9. Renal mass, right, tumor #9 (resection): Renal cell carcinoma with clear and tubular features, Fuhrman nuclear grade II.

NOTE: This lesion has areas reminiscent of a papillary type I carcinoma.

CLINICAL INFORMATION: Allocate Order to Protocol:
Renal Masses Specimen Taken For Protocol: 01 - Yes

Brief Clinical History: Right

Surgical Pathology Report

File in Section 3: Tissue Examination

[page 2 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name:

Accession No.:

MRN:

Date of Report:

PROCEDURE: Pre-Operative Diagnosis: Right Renal Masses Post-Operative Diagnosis: Right Renal Masses Operative Findings: Multiple cystic and solid right renal masses measuring 3 cm to 5 mm.

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Tumor #1
2. KIDNEY, RIGHT, Tumor #2
3. KIDNEY, RIGHT, Tumor #3
4. KIDNEY, RIGHT, Tumor #4
5. KIDNEY, RIGHT, Tumor #5
6. KIDNEY, RIGHT, Tumor #6
7. KIDNEY, RIGHT, Tumor #7
8. KIDNEY, RIGHT, Tumor #8
9. KIDNEY, RIGHT, Tumor #9

GROSS DESCRIPTION: Received fresh are 9 containers labeled with the patient's name, medical record number, and further described as follows:

1. "Tumor #1" is a 1 cm white cyst. The specimen is bisected revealing clear cystic fluid (greater than 80% cystic). Half of the specimen is procured for _____ and the remainder is sent to Surgical Pathology. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is entirely submitted in a white cassette labeled _____ #1 for permanent processing.

2. "Tumor #2" is a 0.4 cm in diameter white cyst. The specimen is bisected revealing a 2 mm yellow nodule inside the cyst. Half of the specimen is procured for _____. The remainder is sent to Surgical Pathology. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is placed in a biopsy bag and is entirely submitted in a white cassette labeled _____ #2 for permanent processing.

3. "Tumor #3" is a 4 cm nodule partially covered by a fibrous capsule with multiple brown cystic nodules (approximately 2 mm in diameter) on the surface. The specimen is bisected revealing a tan, necrotic center. No procurement is performed. The outer surface is inked in black. The specimen is received in Surgical Pathology and is consistent with the above description. Representative sections are submitted in white cassettes labeled _____ A-3D for permanent processing.

4. "Tumor #4" is a 1 cm in diameter cyst. The surface is inked in black. The specimen is bisected. One-fourth of the specimen is sent for procurement for _____. The remainder is sent to Surgical Pathology. The specimen is greater than 90% cystic. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is entirely submitted in a white cassette labeled _____ #4 for permanent processing.

Patient Identification

Surgical Pathology Report

File in Section 3: Tissue Examination

Page 2 of 4

[page 3 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name:

Accession No.:

MRN:

Date of Report:

5. "Tumor #5" is a 1.7 cm well-circumscribed cystic lesion with white, fibrous capsule. The surface is inked in black. The specimen is bisected revealing a cystic surface (approximately 5% cystic) with white solid areas. Approximately 1 cc of tissue not involving the capsule is procured for The remainder is sent to Surgical Pathology. The specimen is received in Surgical Pathology and is consistent with the above description. Representative sections are submitted in white cassettes labeled 5A and 5B for permanent processing.

6. "Tumor #6" is a 2 cm diameter cyst with a white capsule. Cut surface is inked in black. The specimen is bisected revealing a cystic surface (approximately 70% cystic) with a tan nodular area measuring approximately 1 x 1 cm. No procurement is performed. The specimen is received in Surgical Pathology and is consistent with the above description. Representative sections are submitted in white cassettes labeled 6A-6B for permanent processing.

7. "Tumor #7" is a 0.7 cm in diameter white cystic lesion. The specimen is bisected revealing a clear fluid. No procurement is performed. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is entirely submitted in a white cassette labeled for permanent processing.

8. "Tumor #8" is a 3 cm in diameter nodule, well circumscribed. The surface is inked in black. The specimen is bisected revealing a tan, variegated cut surface (approximately 20% cystic). Approximately 1 cc of tissue not involving the capsule is procured for The remainder is sent to Surgical Pathology. Additionally in the container is a piece of fibroadipose tissue measuring 4 x 3 x 1 cm with cautery artery artifact. The specimen is received in Surgical Pathology and is consistent with the above description. Representative sections of the mass are submitted in white cassettes labeled A-8C. Within the adipose tissue, two putative lymph nodes are found and submitted in white cassettes labeled 8D and 8E for permanent processing.

9. "Tumor #9" is a 2.7 cm in diameter cyst. The surface is inked in black. The mass is bisected revealing a light tan, cystic surface (greater than 70% cystic). No procurement is performed. The specimen is received in Surgical Pathology and is consistent with the above description. Representative sections are submitted in white cassettes labeled A-9C for permanent processing.

The procurements were performed by

Gross dictated by

No consultants

Patient Identification

Surgical Pathology Report

File in Section 3: Tissue Examination

Page 3 of 4

[page 4 of 4]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name:
MRN:

Accession No.:
Date of Report:

Patient Identification

Surgical Pathology Report

File in Section 3: Tissue Examination

Page 4 of 4

Triple
2nd primary to
initial TCB tumor.

Source: NCI Genomic Data Commons file b753ee14-58af-4589-841a-cd224e2f6c42 (TCGA-DV-A4W0.16189FB1-65EF-49AF-A8DD-7E0BA7CF7228.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).